FM case AD14224 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/38f6102f-fd87-4232-a4b0-1417106a34e9

Male, 83.6 years: Duct adenocarcinoma, NOS (ICD-O-3 8500/3) of the pancreas; primary biopsied or resected from the pancreas. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
